Somatic mutation profile of tumor specimen TCGA-WZ-A7V5-01A (aliquot TCGA-WZ-A7V5-01A-11D-A435-10) from TCGA case TCGA-WZ-A7V5, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 27.1 years (9,886 days).
Specimen TCGA-WZ-A7V5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 35bfd498-feb2-4196-bedd-510ee31f574e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-WZ-A7V5-10A (Blood Derived Normal), aliquot TCGA-WZ-A7V5-10A-01D-A438-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/25f7e220-dba3-4519-a02b-8555df924707

The open-access MAF lists 43 somatic variants for this specimen: 34 protein-altering or splice-affecting, 5 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 5, Intron 3, Splice Site 2, Nonsense Mutation 1, 5'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKRD30A | c.4082T>C p.M1361T (on ENST00000611781; = p.M1305T on NM_052997.2) | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.038); catalogued as rs1380024966; called by muse, mutect2, varscan2
- CNTFR | c.953C>T p.T318I | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.86); catalogued as rs1471612187; called by muse, mutect2, varscan2
- FREM1 | c.2458C>T p.P820S | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as rs753249073; called by muse, mutect2, varscan2
- IL17RD | c.1624C>G p.L542V | Missense Mutation (SNP) | VAF 16/166 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1186927795; called by muse, mutect2
- SERINC1 | c.1243G>A p.E415K | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT tolerated (0.88); PolyPhen benign (0.003); catalogued as COSV100305394; called by muse, mutect2, varscan2
- SPHKAP | c.905C>T p.S302L | Missense Mutation (SNP) | VAF 17/158 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV60870809; called by muse, mutect2, varscan2
- UTRN | c.9519G>A p.W3173* | Nonsense Mutation (SNP) | VAF 10/67 reads (15%) | catalogued as rs780974577; called by muse, mutect2, varscan2
- WNK3 | c.3715G>A p.G1239S | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.492); catalogued as rs1557150940; called by muse, mutect2, varscan2
- ADGRE5 | c.2158C>G p.Q720E (on ENST00000242786 / NM_078481.4; = p.Q627E on NM_001784.5) | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- AKAP13 | c.320C>G p.A107G | Missense Mutation (SNP) | VAF 21/181 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- AP3B2 | c.248C>T p.A83V | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT tolerated (0.58); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- APP | c.1529A>G p.K510R | Missense Mutation (SNP) | VAF 8/170 reads (5%) | SIFT tolerated (1); PolyPhen possibly damaging (0.794); called by muse, mutect2
- BIRC6 | c.5270C>G p.S1757C | Missense Mutation (SNP) | VAF 134/599 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.646); called by muse, mutect2, varscan2
- CECR2 | c.1187A>T p.K396M (on ENST00000342247 / NM_001290047.2; = p.K213M on NM_001290046.1) | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.315); called by mutect2, varscan2
- CWC22 | c.2230C>G p.Q744E | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- CYP1A1 | c.340C>A p.L114I | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.527); called by muse, mutect2, varscan2
- DNAH17 | c.8330A>G p.E2777G | Missense Mutation (SNP) | VAF 7/78 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.898); called by muse, mutect2
- DNAH5 | c.5710-1G>T p.X1904_splice | Splice Site (SNP) | VAF 7/79 reads (9%) | called by muse, mutect2
- GPR160 | c.275A>T p.Y92F | Missense Mutation (SNP) | VAF 39/160 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- HAUS6 | c.1376+1G>T p.X459_splice | Splice Site (SNP) | VAF 43/235 reads (18%) | called by muse, mutect2, varscan2
- HERC2 | c.5164C>T p.P1722S | Missense Mutation (SNP) | VAF 24/215 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.373); called by muse, mutect2, varscan2
- KIF6 | c.1249G>A p.D417N | Missense Mutation (SNP) | VAF 11/132 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2
- LAMA2 | c.2648C>G p.S883C | Missense Mutation (SNP) | VAF 12/152 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- MCM8 | c.481C>T p.H161Y | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- MFHAS1 | c.459G>C p.Q153H | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- MTMR7 | c.1162C>G p.L388V | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- MYO5A | c.3601C>G p.L1201V | Missense Mutation (SNP) | VAF 9/100 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- NACC1 | c.1449G>C p.K483N | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PUS1 | c.864C>G p.S288R | Missense Mutation (SNP) | VAF 12/123 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SRPRA | c.1037G>C p.R346P | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- TREX1 | c.67G>A p.G23S (on ENST00000625293 / NM_033629.6; = p.G13S on NM_007248.5) | Missense Mutation (SNP) | VAF 9/127 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- WDR88 | c.884A>G p.K295R | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.231); called by muse, mutect2, varscan2
- XPO1 | c.2975C>G p.A992G | Missense Mutation (SNP) | VAF 30/278 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- ZNF217 | c.691_692del p.L231Nfs*2 | Frame Shift Del (DEL) | VAF 10/98 reads (10%) | called by mutect2, pindel
- APOBEC2 | c.462C>G p.L154= | Silent (SNP) | VAF 20/140 reads (14%) | called by muse, mutect2, varscan2
- BRIP1 | c.342A>G p.P114= | Silent (SNP) | VAF 25/144 reads (17%) | catalogued as rs756764576; ClinVar: likely benign; called by muse, mutect2, varscan2
- DNAH2 | c.804A>T p.T268= | Silent (SNP) | VAF 8/51 reads (16%) | called by muse, mutect2, varscan2
- HRC | c.147C>A p.L49= | Silent (SNP) | VAF 9/64 reads (14%) | called by muse, mutect2, varscan2
- PIGS | c.189G>T p.V63= | Silent (SNP) | VAF 10/152 reads (7%) | called by muse, mutect2
- CD58 | c.707-27T>G | Intron (SNP) | VAF 6/38 reads (16%) | called by muse, mutect2
- CP | c.2555-9T>C | Intron (SNP) | VAF 13/66 reads (20%) | called by muse, mutect2, varscan2
- Metazoa_SRP | chr17:18610087 G>A | 5'Flank (SNP) | VAF 33/384 reads (9%) | called by muse, mutect2
- POMZP3 | c.228-158G>C | Intron (SNP) | VAF 8/136 reads (6%) | catalogued as rs762538573; called by muse, mutect2
